CCDI case PBCNIX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a114b6d6-e0e6-4d1b-8cae-0aab50adc838

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,368 days).

Biospecimens (3 samples)
- Sample 0DVZEF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZEM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVZEQ: Tissue type: Tumor; Specimen type: Solid Tissue.
